Surgical pathology report (de-identified scan), TCGA case TCGA-XM-A8RC, project TCGA-THYM (Thymoma), tissue source site MSKCC, specimen TCGA-XM-A8RC-01A (Primary Tumor).

[page 1 of 5]
SURGICAL PATHOLOGY REPORT

* Amended *

Patient: [REDACTED] Accession #: [REDACTED]
MRN: [REDACTED] Service: [REDACTED]
Account: [REDACTED] Date of Procedure: [REDACTED]
(Age: M Date of Receipt: [REDACTED]
Physician: [REDACTED] Date of Amendment: [REDACTED]
CC: [REDACTED]
Patient Address: [REDACTED]

....

Clinical Diagnosis & History:
y/o male with anterior mediastinal mass.

Specimens Submitted:
1: SP: Right lateral margin mediastinal mass (fs)
2: SP: Inferior margin (fs)
3: SP: Superior margin (fs)
4: SP: Left lateral margin (fs)
5: SP: Xiphoid
6: SP: Mediastinal mass

AMENDED DIAGNOSIS:

- 1) MEDIASTINUM, MASS, RIGHT LATERAL MARGIN; BIOPSY:
- BENIGN FIBROADIPOSE TISSUE WITH CAUTERY ARTIFACT.
- 2) MEDIASTINUM, MASS, INFERIOR MARGIN; BIOPSY:
- BENIGN FIBROADIPOSE TISSUE WITH CAUTERY ARTIFACT.
- 3) MEDIASTINUM, MASS, SUPERIOR MARGIN; BIOPSY:
- BENIGN FIBROADIPOSE TISSUE WITH CAUTERY ARTIFACT.
- 4) MEDIASTINUM, MASS, LEFT LATERAL; BIOPSY:
- BENIGN FIBROADIPOSE TISSUE WITH CAUTERY ARTIFACT.
- 5) XIPHOID; PARTIAL RESECTION:
- FRAGMENT OF BENIGN CARTILAGE AND FIBROADIPOSE TISSUE.
- 6) MEDIASTINUM, MASS, EXCISION:
- INVASIVE THYMOMA, WHO TYPE B2.
- THE TUMOR INVADES INTO PERI-THYMIC FAT AND IS ADHERENT TO THE PARIETAL PLEURA.
- THE TUMOR MEASURES 9.5 X 5 X 2.5 CM GROSSLY.
- SURGICAL MARGINS ARE FREE OF TUMOR.
- THREE BENIGN LYMPH NODES (0/3).
- NORMAL THYMUS GLAND SHOWS ATROPHY.
- IMMUNOSTAINS ARE POSITIVE FOR CK AE1/AE3 AND CK 18, FAINTLY POSITIVE FOR EMA AND NEGATIVE FOR C-KIT. CD3, CD5, CD99, AND CD1A STAIN INFILTRATING LYMPHOCYTES. THE MIB-1 PROLIFERATION INDEX IS

** Continued on next page **

ICD O-3
Thymoma, Type B2, malignant
8584/3
Site: C66 Anterior mediastinum - NOS
path C88.1
Mediastinum NOS
C88.3
9/23/12/14

[page 2 of 5]
SURGICAL PATHOLOGY REPORT

Patient: [REDACTED]

MRN: [REDACTED]

Account # [REDACTED]

Accession # [REDACTED]

Physician: [REDACTED]

Service: Thoracic

Date of Report:

----- Page 2 of 5

HIGH AMONG INFILTRATING LYMPHOCYTES.

NOTE: WE HAVE REVIEWED THIS CASE IN CONJUNCTION WITH THE PREVIOUS CYTOLOGY SPECIMEN AND WITH [REDACTED] IN RETROSPECT, THE ATYPICAL CELLS IN THE CYTOLOGY SPECIMEN THAT WERE THOUGHT TO REPRESENT A POORLY DIFFERENTIATED CARCINOMA IN FACT REPRESENT THE EPITHELIAL COMPONENT OF THE THYMOMA. THESE CELLS HAVE LARGE NUCLEI, PROMINENT NUCLEOLI, AND IRREGULAR NUCLEAR CONTOURS.

Note:

This document represents an amended version of the surgical pathology report originally issued on [REDACTED] That report is superseded by the present document. The responsible clinician has been notified.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Special Studies:

Result	Special Stain	Comment
	CD5	
	CD99	
	CD3 (Leu4)	
	CK18	
	CD117	
	MIB-1	
	O10 (CD1a)	
	IMM RECUT	
	NEG CONT	
	RECUT	

Gross Description:

1). The specimen is received fresh for frozen section consultation, labeled "Right lateral margin mediastinal mass" and consists of a piece of soft tissue measuring 1.4 x 0.8 x 0.5 cm. Entirely submitted for frozen section.

Summary of sections:

FSC -- frozen section control

2). The specimen is received fresh for frozen section consultation, labeled "Inferior margin" and consists of a piece of soft tissue measuring 0.4 x 0.2

** Continued on next page **

[page 3 of 5]
SURGICAL PATHOLOGY REPORT

Patient:

MRN:

Account #:

Accession #:

Physician:

Service:

Date of Report:

----- Page 3 of 5

x 0.2 cm. Entirely submitted for frozen section.

Summary of sections:

FSC -- frozen section control

3). The specimen is received fresh for frozen section consultation, labeled "Superior margin" and consists of a piece of soft tissue measuring 0.4 x 0.2 x 0.2 cm. Entirely submitted for frozen section.

Summary of sections:

FSC -- frozen section control

4). The specimen is received fresh for frozen section consultation, labeled "Left lateral margin" and consists of a piece of soft tissue measuring 0.4 x 0.2 x 0.2 cm. Entirely submitted for frozen section.

Summary of sections:

FSC -- frozen section control

5). The specimen is received in formalin and is labeled "xiphoid". It consists of two fragments of tan hemorrhagic bone 2 x 1 x 0.7 and 1 x 0.7 x 0.5 cm. Attached with small fragments of soft tissue. Representative sections are submitted.

Summary of sections:

u undesignated

6). The specimen is received fresh, labeled "mediastinal mass" and consists of an irregular fragment of yellow lobulated fibrofatty tissue measuring 11.5 x 6 by 3 cm, and weighing 65 g. The specimen is oriented by short suture to designate the superior margin. A long suture designated anterior margin. The anterior margin is inked blue, the posterior margin is inked black. Sectioning shows an ill defined tumor mass measuring 9.5 x 5 x 2.5 cm. It has firm white, heterogenous cut surface with areas of yellow necrosis. It is less than 0.1 cm from the deep margin. The surrounding soft tissue consists of a yellow lobulated adipose tissue. Sections are submitted for TFS and electromicroscopy. Section are submitted as follows:

Summary of Sections

T-tumor

s-surrounding tissue

** Continued on next page **

[page 4 of 5]
SURGICAL PATHOLOGY REPORT

Patient:

MRN:

Account #:

Accession #

Physician:

Service:

Date of Report:

Page 4 of 5

Summary of Sections:

Part 1: SP: Right lateral margin mediastinal mass (fs)

Block	Sect.	Site	PCs
1	fsc		1

Part 2: SP: Inferior margin (fs)

Block	Sect.	Site	PCs
1	fsc		1

Part 3: SP: Superior margin (fs)

Block	Sect.	Site	PCs
1	fsc		1

Part 4: SP: Left lateral margin (fs)

Block	Sect.	Site	PCs
1	fsc		1

Part 5: SP: Xiphoid

Block	Sect.	Site	PCs
1	t		2

Part 6: SP: Mediastinal mass

Block	Sect.	Site	PCs
6		{not entered}	
1	u		1

Amendments

Amend Date:

Amended By:

Original Diagnosis:

- 1) MEDIASTINUM, MASS, RIGHT LATERAL MARGIN; BIOPSY:
- BENIGN FIBROADIPOSE TISSUE WITH CAUTERY ARTIFACT.
- 2) MEDIASTINUM, MASS, INFERIOR MARGIN; BIOPSY:
- BENIGN FIBROADIPOSE TISSUE WITH CAUTERY ARTIFACT.
- 3) MEDIASTINUM, MASS, SUPERIOR MARGIN; BIOPSY:
- BENIGN FIBROADIPOSE TISSUE WITH CAUTERY ARTIFACT.
- 4) MEDIASTINUM, MASS, LEFT LATERAL; BIOPSY:

** Continued on next page **

[page 5 of 5]
SURGICAL PATHOLOGY REPORT

Patient:

MRN:

Account #:

Accession #:

Physician:

Service:

Date of Report:

Page 5 of 5

- BENIGN FIBROADIPOSE TISSUE WITH CAUTERY ARTIFACT.

5) XIPHOID; PARTIAL RESECTION:

- FRAGMENT OF BENIGN CARTILAGE AND FIBROADIPOSE TISSUE.

6) MEDIASTINUM, MASS, EXCISION:

- INVASIVE THYMOMA, WHO TYPE B2 WITH TREATMENT EFFECT (30%).

- THE TUMOR INVADES INTO PERI-THYMIC FAT AND IS ADHERENT TO THE

PARIETAL PLEURA.

- THE TUMOR MEASURES 9.5 X 5 X 2.5 CM GROSSLY.

- SURGICAL MARGINS ARE FREE OF TUMOR.

- THREE BENIGN LYMPH NODES (0/3).

- NORMAL THYMUS GLAND SHOWS ATROPHY.

- IMMUNOSTAINS ARE POSITIVE FOR CK AE1/AE3 AND CK 18, FAINTLY POSITIVE

FOR EMA AND NEGATIVE FOR

C-KIT. CD3, CD5, CD99, AND CD1A STAIN INFILTRATING LYMPHOCYTES. THE

MIB-1 PROLIFERATION INDEX IS

HIGH AMONG INFILTRATING LYMPHOCYTES.

NOTE: WE HAVE REVIEWED THIS CASE IN CONJUNCTION WITH THE PREVIOUS CYTOLOGY SPECIMEN AND WITH . IN RETROSPECT, THE ATYPICAL CELLS IN THE CYTOLOGY SPECIMEN THAT WERE THOUGHT TO REPRESENT A POORLY DIFFERENTIATED CARCINOMA IN FACT REPRESENT THE EPITHELIAL COMPONENT OF THE THYMOMA. THESE CELLS HAVE LARGE NUCLEI, PROMINENT NUCLEOLI, AND IRREGULAR NUCLEAR CONTOURS.

*** Report Electronically Signed Out ***

Signed out by

Intraoperative Consultation:

The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

1) FROZEN SECTION DIAGNOSIS: FAT NECROSIS; NO TUMOR SEEN.
PERMANENT DIAGNOSIS: SAME.

2) FROZEN SECTION DIAGNOSIS: BENIGN.
PERMANENT DIAGNOSIS: SAME.

3) FROZEN SECTION DIAGNOSIS: BENIGN.
PERMANENT DIAGNOSIS: SAME.

4) FROZEN SECTION DIAGNOSIS: BENIGN.
PERMANENT DIAGNOSIS: SAME.

Referring Physician Contacted

WAS NOTIFIED VIA E-MAIL ON

AT

** End of Report **

Source: NCI Genomic Data Commons file aeefb683-d7de-40af-9474-ebaf1913df83 (TCGA-XM-A8RC.271D218B-92D0-465C-B3A2-0FF61997D235.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).